Somatic mutation profile of tumor specimen TCGA-55-7227-01A (aliquot TCGA-55-7227-01A-11D-2036-08) from TCGA case TCGA-55-7227, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 77.9 years (28,458 days).
Specimen TCGA-55-7227-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0bfa896a-57ec-4fa5-adc4-bc78c3478ed7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-7227-10A (Blood Derived Normal), aliquot TCGA-55-7227-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78e931f1-010b-4321-9b21-f60fa0f95f06

The open-access MAF lists 176 somatic variants for this specimen: 133 protein-altering or splice-affecting, 36 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 36, Nonsense Mutation 7, Splice Site 3, In Frame Del 2, Frame Shift Del 2, Splice Region 2, 5'Flank 2, 3'Flank 2, 3'UTR 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.303_308del p.E102_I103del | In Frame Del (DEL) | VAF 13/53 reads (25%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 21/49 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AADAT | c.568A>G p.T190A | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as rs1362627395, COSV61787398; called by muse, mutect2, varscan2
- ABCA10 | c.330G>T p.E110D | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs1425578032, COSV52224015; called by muse, mutect2, varscan2
- ADAMTS2 | c.2279G>A p.S760N | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as COSV52379265; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3367C>A p.Q1123K | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV54453104; called by muse, mutect2, varscan2
- ADARB1 | c.2121G>T p.E707D (on ENST00000360697 / NM_001346687.2; = p.E667D on NM_001112.4) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.009); catalogued as COSV62344941; called by muse, mutect2, varscan2
- AKR1B15 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71152156; called by muse, mutect2, varscan2
- AMY2B | c.42G>T p.W14C | Missense Mutation (SNP) | VAF 60/259 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.76); catalogued as COSV100796288, COSV100796516; called by muse, mutect2, varscan2
- ANKK1 | c.1975G>T p.G659C | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58272481; called by muse, mutect2, varscan2
- ANKRD44 | c.1612T>C p.Y538H | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56557698; called by muse, mutect2, varscan2
- AP3S1 | c.101A>T p.E34V | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV57475235; called by muse, mutect2, varscan2
- ARHGAP10 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs550595353, COSV60600972; called by muse, mutect2, varscan2
- ATP2B3 | c.698A>T p.Q233L | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV54850927; called by muse, mutect2, varscan2
- AUP1 | c.1077G>T p.K359N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.37); catalogued as COSV57817656; called by muse, mutect2, varscan2
- B4GALNT2 | c.947-2A>G p.X316_splice | Splice Site (SNP) | VAF 35/143 reads (24%) | catalogued as rs1433007530, COSV55926735; called by muse, mutect2, varscan2
- BCAS1 | c.1381T>C p.S461P | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV65087095; called by muse, mutect2, varscan2
- BSN | c.7817G>A p.R2606Q | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1056155060, COSV56519234; called by mutect2, varscan2
- CACNA1C | c.2353G>T p.E785* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as rs553099939, COSV59731737; called by muse, mutect2, varscan2
- CCT8L2 | c.524C>A p.S175Y | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.216); catalogued as rs759549283, COSV63462836; called by muse, mutect2, varscan2
- CDHR2 | c.2402T>A p.V801E | Missense Mutation (SNP) | VAF 61/201 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56140473; called by muse, mutect2, varscan2
- CFHR1 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.828); catalogued as COSV100258899, COSV57627624; called by muse, mutect2, varscan2
- CHTOP | c.481G>T p.G161C | Missense Mutation (SNP) | VAF 58/243 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV64155112, COSV64155261; called by muse, mutect2, varscan2
- CKAP5 | c.3084A>C p.E1028D | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as COSV56369175; called by muse, mutect2, varscan2
- CLCN1 | c.741C>A p.S247R | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58370845; called by muse, mutect2, varscan2
- CLSPN | c.2384G>T p.R795L | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as COSV52052599; called by muse, mutect2, varscan2
- CNKSR2 | c.1843G>C p.E615Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54258816; called by muse, mutect2, varscan2
- COL21A1 | c.2522C>T p.P841L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.946); catalogued as rs1486238937, COSV55166961; called by muse, mutect2, varscan2
- CPB1 | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51574341; called by muse, mutect2, varscan2
- CSPG4 | c.4199C>A p.P1400Q | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV57896786; called by muse, mutect2, varscan2
- CYP4F11 | c.1129C>A p.Q377K | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV56127801; called by muse, mutect2, varscan2
- DCAF11 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as COSV58109595; called by muse, mutect2, varscan2
- DENND2B | c.191G>T p.R64L | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV58204703; called by muse, mutect2, varscan2
- DNAJB4 | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV66131787; called by muse, mutect2, varscan2
- DOCK2 | c.4739T>C p.L1580S | Missense Mutation (SNP) | VAF 81/228 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV56964511; called by muse, mutect2, varscan2
- FAM171A1 | c.1062C>G p.D354E | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65314519; called by muse, mutect2, varscan2
- FAT3 | c.11306C>A p.T3769K | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV53095986, COSV53126111; called by muse, mutect2
- FBXO38 | c.1271C>T p.S424L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV57028722, COSV57029507; called by muse, mutect2, varscan2
- FCN2 | c.703C>A p.L235M | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.832); catalogued as COSV52477391; called by muse, mutect2, varscan2
- FIGNL1 | c.1099G>T p.E367* | Nonsense Mutation (SNP) | VAF 51/168 reads (30%) | catalogued as COSV63553654; called by muse, mutect2, varscan2
- FN1 | c.4778-1G>A p.X1593_splice | Splice Site (SNP) | VAF 11/49 reads (22%) | catalogued as rs1195701016, COSV60555519; called by muse, mutect2
- GDAP1 | c.998G>C p.G333A | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.036); catalogued as COSV55186040; called by muse, mutect2, varscan2
- GLRA3 | c.725G>A p.C242Y | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV56863650; called by muse, mutect2, varscan2
- HAPLN1 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773059273, COSV57148019; called by muse, mutect2
- HGSNAT | c.1131G>T p.E377D | Missense Mutation (SNP) | VAF 87/321 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV52817535; called by muse, mutect2, varscan2
- HMCN1 | c.12929A>G p.H4310R | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV54909147; called by muse, mutect2, varscan2
- HYOU1 | c.133A>G p.M45V | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.268); catalogued as rs568395407, COSV68216145; called by muse, mutect2, varscan2
- IFIT1B | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 51/295 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65663514; called by muse, mutect2, varscan2
- ITPR1 | c.3414G>T p.Q1138H (on ENST00000354582; = p.Q1123H on NM_002222.7) | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.632); catalogued as COSV100231030; called by muse, mutect2, varscan2
- ITPR1 | c.3415G>T p.G1139C (on ENST00000354582; = p.G1124C on NM_002222.7) | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV100231036; called by muse, mutect2, varscan2
- KCNA2 | c.880C>A p.R294S | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV60368715, COSV60370638; called by muse, mutect2, varscan2
- KCNN3 | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.646); catalogued as COSV55219206; called by muse, mutect2
- KCNV2 | c.225C>A p.D75E | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV66056547; called by muse, mutect2, varscan2
- KDR | c.2690A>T p.N897I | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55767751; called by muse, mutect2, varscan2
- KLHL23 | c.137T>G p.I46R | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV55867951; called by muse, mutect2, varscan2
- KLHL3 | c.1165G>T p.A389S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV59054259, COSV59055210; called by muse, mutect2, varscan2
- KRTAP19-3 | c.116G>A p.C39Y | Missense Mutation (SNP) | VAF 77/328 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV61854830; called by muse, mutect2, varscan2
- KRTAP27-1 | c.443C>A p.S148Y | Missense Mutation (SNP) | VAF 51/209 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV67001317; called by muse, varscan2
- LAD1 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs552773617, COSV66212219; called by muse, mutect2, varscan2
- LAMA3 | c.8122G>A p.V2708I (on ENST00000313654 / NM_198129.4; = p.V1099I on NM_000227.6) | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52536729, COSV52543879; called by muse, mutect2, varscan2
- LCN9 | c.470A>G p.N157S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.308); catalogued as COSV52991253; called by muse, mutect2, varscan2
- LIPI | c.934T>A p.C312S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV60712613; called by muse, mutect2, varscan2
- LIX1L | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs782159758, COSV100811070, COSV63417143; called by muse, mutect2, varscan2
- LTBP2 | c.3709G>A p.E1237K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.717); catalogued as rs769155905, COSV56209676; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MARCHF1 | c.229C>A p.Q77K (on ENST00000274056; = p.Q60K on NM_017923.4) | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV56818881, COSV99922290; called by muse, mutect2, varscan2
- MARCHF4 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.782); catalogued as rs1487256002, COSV56105755; called by muse, mutect2, varscan2
- MFAP3L | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.269); catalogued as COSV64372346; called by muse, mutect2, varscan2
- MST1R | c.142A>G p.S48G | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.557); catalogued as COSV56569989; called by muse, mutect2
- MYO7A | c.1217T>A p.L406Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68685177; called by muse, varscan2
- MYT1 | c.1225G>T p.G409C | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.502); catalogued as rs1226232010, COSV60507495; called by muse, mutect2, varscan2
- NAA16 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65065465; called by muse, mutect2, varscan2
- NAP1L3 | c.779C>G p.A260G | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.067); catalogued as COSV59076089; called by muse, mutect2, varscan2
- NFAM1 | c.272G>A p.R91K | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV61195496; called by muse, mutect2, varscan2
- NRXN3 | c.530G>T p.R177L (on ENST00000557594 / NM_001272020.2; = p.R809L on NM_004796.6) | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV55333269; called by muse, mutect2, varscan2
- NUP210L | c.1206C>G p.D402E | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55150038; called by muse, mutect2, varscan2
- OR1L3 | c.554T>A p.L185Q | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59169946; called by muse, mutect2, varscan2
- OR2A5 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as rs749106253, COSV68738848; called by muse, mutect2, varscan2
- OR6C1 | c.937T>A p.*313Rext*5 | Nonstop Mutation (SNP) | VAF 24/62 reads (39%) | catalogued as COSV101110505; called by muse, mutect2, varscan2
- OR8U1 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100163825; called by muse, mutect2, varscan2
- P2RY8 | c.143T>C p.L48P | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101184008; called by muse, mutect2, varscan2
- PAPOLB | c.1029A>T p.K343N | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.373); catalogued as COSV68201670; called by muse, mutect2, varscan2
- PARD3 | c.544C>G p.Q182E | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.017); catalogued as COSV60752458; called by muse, mutect2, varscan2
- PATJ | c.215C>A p.S72* | Nonsense Mutation (SNP) | VAF 11/76 reads (14%) | catalogued as COSV57164574; called by muse, mutect2, varscan2
- PCDH15 | c.4797G>T p.Q1599H | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.438); catalogued as COSV57277141; called by muse, mutect2, varscan2
- PCDHA9 | c.2158G>T p.V720L | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1472245010, COSV65327822; called by muse, mutect2, varscan2
- PCDHB16 | c.367G>T p.V123L | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.997); catalogued as rs1307739360, COSV53364217; called by muse, mutect2, varscan2
- PCLO | c.7108G>T p.E2370* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV61621459, COSV61642114; called by muse, mutect2, varscan2
- PIGA | c.1332G>C p.W444C | Missense Mutation (SNP) | VAF 58/103 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61237873; called by muse, mutect2, varscan2
- PLCG2 | c.480-1G>T p.X160_splice | Splice Site (SNP) | VAF 62/270 reads (23%) | catalogued as COSV63871121; called by muse, mutect2, varscan2
- POT1 | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV62931218; called by muse, mutect2, varscan2
- POU2F1 | c.1132C>T p.R378C (on ENST00000541643 / NM_001365848.1; = p.R401C on NM_002697.4) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54818783; called by muse, mutect2, varscan2
- PRDM9 | c.565C>T p.H189Y | Missense Mutation (SNP) | VAF 79/228 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.303); catalogued as COSV57007987, COSV99690862; called by muse, mutect2, varscan2
- PRSS38 | c.675G>C p.M225I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.066); catalogued as COSV64540751; called by muse, varscan2
- RLBP1 | c.392T>A p.L131Q | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV51528444; called by muse, mutect2, varscan2
- S1PR1 | c.835G>T p.D279Y | Missense Mutation (SNP) | VAF 67/254 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59513440; called by muse, mutect2, varscan2
- SEMA3D | c.2113C>A p.L705I | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.028); catalogued as COSV52396190; called by muse, mutect2, varscan2
- SEZ6 | c.2878C>A p.P960T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV99255753; called by muse, varscan2
- SF1 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs1475766979, COSV57114956; called by muse, mutect2, varscan2
- SIPA1L2 | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 64/222 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780625282, COSV53384034; called by muse, mutect2, varscan2
- SLC1A3 | c.1156G>T p.V386F | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54317412; called by muse, mutect2, varscan2
- SMG5 | c.2377T>A p.F793I | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62435940; called by muse, mutect2, varscan2
- SPAG5 | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV58802293; called by muse, mutect2
- SPEF2 | c.4166A>G p.Y1389C | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs530386441, COSV57429856; called by muse, mutect2, varscan2
- SPRY1 | c.320G>T p.R107M | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59338628; called by muse, varscan2
- SVEP1 | c.5210A>G p.N1737S | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.858); catalogued as COSV52840361; called by muse, mutect2, varscan2
- TARBP1 | c.1917G>T p.M639I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.344); catalogued as COSV50188380; called by muse, mutect2, varscan2
- TFAP2D | c.952G>T p.G318* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as COSV50426487; called by muse, mutect2, varscan2
- TMCC1 | c.396G>C p.K132N | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.42); catalogued as COSV101282065, COSV67873433; called by muse, mutect2, varscan2
- TNR | c.118G>C p.V40L | Missense Mutation (SNP) | VAF 55/204 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.013); catalogued as COSV54891961; called by muse, mutect2, varscan2
- TPST2 | c.413A>T p.Q138L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.379); catalogued as COSV58680364; called by muse, mutect2, varscan2
- TTN | c.11454T>A p.N3818K (on ENST00000591111; = p.N3772K on NM_003319.4) | Missense Mutation (SNP) | VAF 51/194 reads (26%) | catalogued as COSV60133018; called by muse, mutect2, varscan2
- UCMA | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV66321749, COSV66321775; called by muse, mutect2, varscan2
- USP13 | c.900G>T p.G300= | Splice Region (SNP) | VAF 13/48 reads (27%) | catalogued as COSV55866781, COSV55866918; called by muse, mutect2, varscan2
- VAC14 | c.2135T>G p.L712R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV55754632; called by muse, mutect2, varscan2
- XIRP2 | c.23C>A p.S8Y | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV54708923, COSV54740698, COSV99739841; called by muse, mutect2, varscan2
- ZC3H14 | c.1132A>C p.K378Q | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV51770678; called by muse, mutect2, varscan2
- ZFPM2 | c.399G>T p.M133I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV68284812, COSV68294102; called by muse, mutect2, varscan2
- ZNF142 | c.1768C>T p.H590Y (on ENST00000411696 / NM_001379660.1; = p.H390Y on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV68744150; called by muse, mutect2, varscan2
- ZNF521 | c.1040T>C p.V347A | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV64128169; called by muse, mutect2, varscan2
- ZNF536 | c.3897T>A p.G1299= | Splice Region (SNP) | VAF 50/189 reads (26%) | catalogued as COSV62826293; called by muse, mutect2, varscan2
- ZNF75D | c.1483C>A p.H495N | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66132894; called by muse, mutect2, varscan2
- ZNF77 | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.127); catalogued as COSV58822094; called by muse, mutect2, varscan2
- ZNF781 | c.83C>A p.A28D | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV62201733; called by muse, mutect2, varscan2
- ZNF831 | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 51/141 reads (36%) | catalogued as COSV64041565; called by muse, mutect2, varscan2
- ZNF91 | c.1334G>T p.W445L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1427942998, COSV100322673, COSV56088272; called by muse, mutect2, varscan2
- ZYX | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs746277510, COSV59556727; called by muse, mutect2, varscan2
- DHX9 | c.2948_2968del p.G983_D989del | In Frame Del (DEL) | VAF 14/80 reads (18%) | called by mutect2, pindel
- ELF3 | c.236_244delinsC p.Q79Pfs*10 | Frame Shift Del (DEL) | VAF 27/172 reads (16%) | called by pindel, varscan2*
- IGKV2-30 | c.250C>G p.P84A | Missense Mutation (SNP) | VAF 62/251 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- IGKV3D-20 | c.225G>T p.R75S | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- MAGEB6B | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 31/55 reads (56%) | called by muse, mutect2, varscan2
- SLC7A13 | c.900del p.F300Lfs*5 | Frame Shift Del (DEL) | VAF 68/166 reads (41%) | called by mutect2, pindel, varscan2
- SYNCRIP | c.273_274dup p.S92Kfs*9 | Frame Shift Ins (INS) | VAF 20/63 reads (32%) | called by mutect2, pindel, varscan2
- BEGAIN | c.1347C>T p.Y449= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs1381558237, COSV100766953; called by muse, mutect2, varscan2
- CAMSAP2 | c.1233T>C p.I411= (on ENST00000236925 / NM_001297707.2; = p.I400= on NM_203459.3) | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV52672483; called by muse, mutect2
- CKAP4 | c.1155C>T p.H385= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs371266776; called by muse, mutect2, varscan2
- COL4A4 | c.3069A>G p.P1023= | Silent (SNP) | VAF 40/161 reads (25%) | catalogued as COSV61633284; called by muse, mutect2, varscan2
- CPA1 | c.252C>T p.I84= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV50570790, COSV50572598; called by muse, mutect2, varscan2
- CYFIP2 | c.2496G>T p.T832= (on ENST00000616178 / NM_001291722.2; = p.T807= on NM_014376.4) | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs369405267, COSV56637047; called by muse, mutect2
- CYP7B1 | c.636A>C p.L212= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV59590784; called by muse, mutect2, varscan2
- DCDC1 | c.4848G>A p.Q1616= (on ENST00000597505 / NM_001367979.1; = p.Q723= on NM_020869.3) | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV57999948, COSV58002811; called by muse, mutect2, varscan2
- DNAH3 | c.9522C>T p.T3174= | Silent (SNP) | VAF 28/137 reads (20%) | catalogued as COSV54515665; called by muse, mutect2, varscan2
- GIMAP8 | c.999G>T p.L333= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV56232188; called by muse, mutect2, varscan2
- INHBB | c.423C>T p.S141= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs376065523, COSV54678440; called by muse, mutect2, varscan2
- LRP4 | c.2358C>T p.H786= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs371677748; called by mutect2, varscan2
- LY6H | c.258A>G p.S86= | Silent (SNP) | VAF 38/160 reads (24%) | catalogued as rs749376436, COSV61370860; called by muse, mutect2, varscan2
- OR11H6 | c.924T>C p.Y308= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV59644444; called by muse, mutect2, varscan2
- OR2AK2 | c.135G>T p.L45= | Silent (SNP) | VAF 60/198 reads (30%) | catalogued as COSV63554724; called by muse, mutect2, varscan2
- OR4D6 | c.102G>A p.V34= | Silent (SNP) | VAF 46/131 reads (35%) | catalogued as COSV55659852, COSV55660016; called by muse, mutect2, varscan2
- OR51S1 | c.426G>T p.A142= | Silent (SNP) | VAF 29/137 reads (21%) | catalogued as COSV59057860, COSV59058831; called by muse, mutect2, varscan2
- P2RY8 | c.144G>T p.L48= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV101184007; called by muse, mutect2, varscan2
- PCDHGC5 | c.1197T>A p.P399= | Silent (SNP) | VAF 44/186 reads (24%) | catalogued as COSV52755119; called by muse, mutect2, varscan2
- PMP2 | c.192C>T p.S64= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs751438413, COSV56267185, COSV56267230; called by muse, mutect2, varscan2
- PSIP1 | c.123C>T p.P41= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs779267116, COSV66254853; called by muse, mutect2, varscan2
- ROBO2 | c.819A>G p.K273= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV59916202; called by muse, mutect2, varscan2
- RYR2 | c.14106T>C p.D4702= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV63691656; called by muse, mutect2, varscan2
- SENP1 | c.186A>T p.T62= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV50292344; called by muse, mutect2, varscan2
- SLC22A9 | c.6C>T p.A2= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as COSV54167805; called by muse, mutect2, varscan2
- SLC8A3 | c.453T>C p.S151= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as rs745605771, COSV100776382, COSV63522449; called by muse, mutect2, varscan2
- SNRNP200 | c.2217G>T p.R739= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV60490804; called by muse, mutect2, varscan2
- SPEG | c.5535A>T p.A1845= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV56671537; called by muse, mutect2, varscan2
- TAF1L | c.42C>T p.T14= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as rs1257805302, COSV54263593, COSV99645184; called by muse, mutect2, varscan2
- TARBP1 | c.4422G>T p.P1474= | Silent (SNP) | VAF 30/110 reads (27%) | catalogued as COSV50188314; called by muse, mutect2, varscan2
- TMEFF1 | c.651A>T p.R217= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV58494441; called by muse, mutect2, varscan2
- TRIM49 | c.1257T>A p.T419= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as rs753083133, COSV100316040; called by muse, mutect2, varscan2
- TRPS1 | c.1830G>A p.S610= (on ENST00000220888 / NM_001330599.2; = p.S623= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as rs751550383, COSV55237292, COSV55246645; called by muse, mutect2, varscan2
- TSHZ3 | c.2983C>T p.L995= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV53674350, COSV53678738; called by muse, mutect2, varscan2
- ZBTB44 | c.675C>G p.S225= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV63537498; called by muse, mutect2, varscan2
- ZIC3 | c.808C>A p.R270= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as COSV54974900; called by muse, mutect2, varscan2
- AC055839.2 | chr17:5501829 G>A | 5'Flank (SNP) | VAF 30/61 reads (49%) | catalogued as rs749226290, COSV52561212; called by muse, mutect2, varscan2
- AC116366.2 | c.-638+11006G>T | Intron (SNP) | VAF 56/166 reads (34%) | catalogued as COSV61819296; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826894 C>A | 3'Flank (SNP) | VAF 34/52 reads (65%) | called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826895 C>A | 3'Flank (SNP) | VAF 34/55 reads (62%) | called by muse, mutect2, varscan2
- FUT7 | chr9:137034655 C>A | 5'Flank (SNP) | VAF 49/180 reads (27%) | called by muse, mutect2, varscan2
- SPATA8 | n.222A>T | RNA (SNP) | VAF 22/72 reads (31%) | catalogued as COSV60704913; called by muse, varscan2
- XIRP2 | c.*1124C>G | 3'UTR (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99742650; called by muse, mutect2, varscan2
